Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6481, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6481-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONSIL, RIGHT, BIOPSY: MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA.

2) TONSIL, RIGHT #2, BIOPSY: MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA, EXTENDING TO TISSUE EDGES, NEGATIVE FOR LYMPHOVASCULAR INVASION.

**Electronically Signed Out by [REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Right tonsil

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)right tonsil; 2)right tonsil #2

GROSS DESCRIPTION:

1) SOURCE: Right Tonsil

The specimen is received fresh in a container labeled with the patient's name and MR number and "right tonsil" and consists of two pieces of white-tan soft tissue measuring 0.5 x 0.3 x 0.2 cm and 0.3 x 0.2 x 0.2 cm respectively. The entire specimen is submitted for frozen section diagnosis.

Summary of sections: 1AFSC, entire specimen, 2/1.

2) SOURCE: Right Tonsil #2

Received fresh labeled with the patient's name and "right tonsil" are two pink-red, focally congested tissue fragments measuring 0.6 and 0.9 cm in greatest dimension which are submitted entirely.

Summary of sections: 2A, 2/1.

Dictated by [REDACTED]

[page 2 of 2]
[REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Right Tonsil

FROZEN SECTION DIAGNOSIS: AT LEAST SQUAMOUS CELL CARCINOMA IN SITU. [REDACTED]

Electronically signed by: [REDACTED] Attending Pathologist

SNOMED: T-C5100,T-C5100,M-80703,

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 41acc8f7-25d9-403c-86f6-2a8a3b0492bf (TCGA-CR-6481.4BFDA7C2-A13F-4271-AF8E-96A9B3456DEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).